Gene-level copy-number profile of tumor specimen TCGA-97-A4M0-01A from TCGA case TCGA-97-A4M0, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.8 years (22,206 days).
Specimen TCGA-97-A4M0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f1056708-0fd8-46de-9d33-8bbcd7fe0c8d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-A4M0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ed2cf2d-8785-43ea-8804-7a1ed8231a57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 113; copy number 1: 13,421; copy number 2: 38,801; copy number 3: 7,241; copy number 4: 223; copy number 5: 15; copy number 8: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-A4M0-01A-11D-A24O-01): tumor purity 0.55, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–21,878,256, 113 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:36,054,197–36,656,163, 15 genes, copy number 5 (within-gene range 3–5): ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2.
- chr17:12,760,140–12,991,643, 4 genes, copy number 8 (within-gene range 3–8): AC005358.1, ARHGAP44, MIR1269B, AC005274.1.

Autosomal genes at a single copy (total copy number 1): 13,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
